Gene-level copy-number profile of tumor specimen ALCH-B6Y0-TTP1-A from ALCHEMIST case ALCH-B6Y0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.1 years (24,153 days).
Specimen ALCH-B6Y0-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 25ff7633-f151-4888-aa56-e8aa1c746e08.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B6Y0-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/9d4bb618-f572-45a7-997e-fdbe5f70e728

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 38; copy number 1: 6,307; copy number 2: 51,460; copy number 3: 908; copy number 4: 138; copy number 5: 39; copy number 6: 3; copy number 7: 1; copy number 8: 1; copy number 10: 1; copy number 24: 3; copy number 31: 1.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:8,831,007–8,879,190, 3 genes (within-gene range 0–2): RPL23AP19, ENO1, MIR6728.
- chr13:19,818,121–19,865,048, 4 genes: ST6GALNAC4P1, ZMYM5, AL355001.1, AL355001.2.
- chr14:63,684,216–63,728,065, 1 gene: SGPP1.
- chr14:74,377,818–74,378,418, 1 gene: RPS2P2.
- chr15:20,545,576–20,549,444, 1 gene: AC023310.3.
- chr16:46,955,362–47,035,385, 4 genes: DNAJA2, AC018845.3, AC018845.1, AC018845.2.
- chr19:1,228,287–1,238,027, 1 gene (within-gene range 0–1): CBARP.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 49 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:20,531,856–20,541,800, 1 gene, copy number 8: GOLGA6L6.
- chr15:20,570,886–20,571,175, 1 gene, copy number 6: RN7SL759P.
- chr15:21,405,401–22,095,857, 38 genes, copy number 5 (within-gene range 0–11): POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2, MIR5701-3, OR11J6P, AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P, OR4H6P, OR4M2, OR4N4.
- chr19:1,248,553–1,259,140, 1 gene, copy number 5: MIDN.
- chr21:44,107,373–44,210,114, 5 genes, copy number 6–31 (within-gene range 2–31): PWP2, GATD3A, LINC01678, AP001056.2, AP001056.1.
- chr21:44,217,014–44,244,993, 3 genes, copy number 24: ICOSLG, AP001059.2, AP001059.1.

Autosomal genes at a single copy (total copy number 1): 3,475. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
